Somatic mutation profile of tumor specimen HTMCP-03-06-02394-01A (aliquot HTMCP-03-06-02394-01A-01D-10409) from CGCI case HTMCP-03-06-02394, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 71.7 years (26,203 days).
Specimen HTMCP-03-06-02394-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b90ac24-c214-4279-bcc3-9287cd691db8.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02394-10A (Blood Derived Normal), aliquot HTMCP-03-06-02394-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1527a710-ce45-4e88-8a14-2170765fab46

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Nonsense Mutation 2, Silent 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.11060G>A p.R3687H | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs762481926, COSV67979116; called by muse, mutect2, varscan2
- CEMIP | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775636535; called by muse, mutect2, varscan2
- RP1L1 | c.1805C>T p.T602M | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs752031060; called by muse, mutect2, varscan2
- CFAP61 | c.215A>G p.D72G | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FCGBP | c.3340G>A p.A1114T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- MAGEC2 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 38/123 reads (31%) | called by muse, mutect2, varscan2
- MAP3K6 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- MYO18B | c.4042A>T p.K1348* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- PCDHA12 | c.2118G>A p.A706= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs996962116, COSV56537634; called by muse, mutect2, varscan2
- AC006548.1 | n.53_54del | RNA (DEL) | VAF 122/364 reads (34%) | called by mutect2, pindel*, varscan2
